Somatic mutation profile of tumor specimen TCGA-J7-A8I2-01A (aliquot TCGA-J7-A8I2-01A-12D-A35Z-10) from TCGA case TCGA-J7-A8I2, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 75.1 years (27,431 days).
Specimen TCGA-J7-A8I2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 185c32b4-a9dd-488e-b4f1-d39b5a4cfe39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J7-A8I2-10A (Blood Derived Normal), aliquot TCGA-J7-A8I2-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86026f0d-e597-4a38-9750-e02d52aa8e2d

The open-access MAF lists 57 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 12, Nonsense Mutation 3, Frame Shift Del 2, 3'UTR 1, Intron 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*174A>G | 3'UTR (SNP) | VAF 24/53 reads (45%) | catalogued as rs121913485, CM960657, COSV53390174; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ALK | c.2402T>C p.I801T | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.42); catalogued as COSV101202171; called by muse, mutect2, varscan2
- ALMS1 | c.6697A>G p.I2233V | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); catalogued as rs755011344, COSV100042773; called by muse, mutect2, varscan2
- ANKRD27 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100042907; called by muse, mutect2, varscan2
- CEP250 | c.7301C>T p.P2434L | Missense Mutation (SNP) | VAF 66/110 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100698989; called by muse, mutect2, varscan2
- CFAP100 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100729281; called by muse, mutect2
- CLASP1 | c.1270A>G p.I424V | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99755270; called by muse, mutect2, varscan2
- COL14A1 | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as rs145606030; called by muse, mutect2, varscan2
- DMRTA2 | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.344); catalogued as COSV101288880; called by muse, mutect2
- DZIP1 | c.1213G>C p.D405H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs752862567, COSV100714009, COSV100714117; called by muse, mutect2, varscan2
- EPPK1 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV101599875; called by muse, mutect2, varscan2
- HECTD4 | c.12086C>G p.A4029G | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV101107784; called by muse, mutect2, varscan2
- HERC1 | c.8560G>A p.D2854N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.111); catalogued as COSV101496629, COSV71250931; called by muse, mutect2, varscan2
- HERC1 | c.8341G>A p.D2781N | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.984); catalogued as COSV101496630; called by muse, mutect2, varscan2
- HIF1A | c.2359A>G p.M787V | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs761301966, COSV100048856; called by muse, mutect2, varscan2
- HOXB2 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 98/141 reads (70%) | catalogued as COSV100344690; called by muse, mutect2, varscan2
- KCNF1 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54465464; called by muse, mutect2, varscan2
- KLC2 | c.91_92del p.L31Afs*15 | Frame Shift Del (DEL) | VAF 42/108 reads (39%) | catalogued as rs1231406020; called by pindel, varscan2
- LIF | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs753939297, COSV50777222; called by muse, mutect2, varscan2
- LLGL1 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV100375444; called by muse, mutect2, varscan2
- LPAR6 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs767102500, COSV57304894; called by muse, mutect2, varscan2
- MAP1B | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV99702529; called by muse, mutect2, varscan2
- NEDD4 | c.1346A>G p.N449S | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100163792; called by muse, mutect2, varscan2
- NFE2L2 | c.1017C>G p.F339L | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV101229385, COSV67960987; called by muse, mutect2, varscan2
- P3H4 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.198); catalogued as rs1244824462, COSV58635338; called by muse, mutect2, varscan2
- PCDH18 | c.1649G>C p.G550A | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.203); catalogued as COSV100787380; called by muse, mutect2, varscan2
- PLPP3 | c.526A>T p.I176F | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100984706; called by muse, mutect2, varscan2
- PNPT1 | c.1969A>G p.M657V | Missense Mutation (SNP) | VAF 158/401 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs766570634, COSV99570097; called by muse, mutect2, varscan2
- RALA | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 131/303 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99143420; called by muse, mutect2, varscan2
- SCIN | c.1933G>T p.V645F (on ENST00000297029 / NM_001112706.3; = p.V398F on NM_033128.3) | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99764942; called by muse, mutect2, varscan2
- SGO1 | c.1073G>C p.R358T | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV55425598; called by muse, mutect2, varscan2
- SH2B3 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as rs746192970, COSV100374320; called by muse, mutect2, varscan2
- SLC37A1 | c.954C>G p.I318M | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100721719; called by muse, mutect2, varscan2
- TRPM7 | c.5167A>G p.M1723V | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV57913279; called by muse, mutect2, varscan2
- TRPM7 | c.1933G>T p.G645C | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV57921357; called by muse, mutect2, varscan2
- TSN | c.19T>A p.F7I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101067513; called by muse, mutect2, varscan2
- UBE2O | c.2084C>G p.A695G | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.836); catalogued as COSV100084698; called by muse, mutect2, varscan2
- USF3 | c.169A>G p.M57V | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100325442; called by muse, mutect2, varscan2
- USP47 | c.3416A>G p.K1139R (on ENST00000399455 / NM_001372095.1; = p.K1051R on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100359678; called by muse, mutect2, varscan2
- YAP1 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.494); catalogued as COSV99176172; called by muse, mutect2, varscan2
- ZMYM3 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 190/206 reads (92%) | catalogued as COSV100078016; called by muse, varscan2
- EP300 | c.3262-29_3263del p.X1088_splice | Splice Site (DEL) | VAF 36/130 reads (28%) | called by mutect2, pindel, varscan2
- KDM6A | c.4188del p.L1396Ffs*142 | Frame Shift Del (DEL) | VAF 37/54 reads (69%) | called by mutect2, pindel, varscan2
- SIX1 | c.128dup p.H44Afs*22 | Frame Shift Ins (INS) | VAF 28/80 reads (35%) | called by mutect2, pindel, varscan2
- ABLIM2 | c.528C>T p.G176= | Silent (SNP) | VAF 62/137 reads (45%) | catalogued as COSV99589790; called by muse, mutect2, varscan2
- APEX2 | c.970C>T p.L324= | Silent (SNP) | VAF 53/58 reads (91%) | catalogued as COSV100238425; called by muse, mutect2, varscan2
- ATRAID | c.24C>T p.H8= | Silent (SNP) | VAF 155/327 reads (47%) | catalogued as rs769613846, COSV100143344; called by muse, mutect2, varscan2
- BCL2A1 | c.262A>C p.R88= | Silent (SNP) | VAF 11/164 reads (7%) | catalogued as COSV99144341; called by muse, mutect2
- DCHS1 | c.6663C>T p.H2221= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as rs199804192, COSV100202176; called by muse, mutect2, varscan2
- FKBP1A | c.237A>C p.P79= | Silent (SNP) | VAF 154/257 reads (60%) | catalogued as COSV101098376; called by muse, mutect2, varscan2
- LAMA5 | c.3621C>T p.I1207= | Silent (SNP) | VAF 150/218 reads (69%) | catalogued as rs750388907, COSV53362177; called by muse, mutect2, varscan2
- NPAS4 | c.558C>T p.P186= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as rs569596792, COSV100215059; called by muse, mutect2, varscan2
- PLEKHA3 | c.339G>T p.L113= | Silent (SNP) | VAF 119/266 reads (45%) | catalogued as COSV99317756; called by muse, mutect2, varscan2
- SETBP1 | c.2502G>A p.L834= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV99953648; called by muse, mutect2, varscan2
- SPPL2A | c.1317G>A p.S439= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs780968695, COSV55940647; called by muse, mutect2, varscan2
- TPO | c.1171C>T p.L391= | Silent (SNP) | VAF 257/587 reads (44%) | catalogued as COSV100221408; called by muse, mutect2, varscan2
- FBXW7 | c.502-2598C>T | Intron (SNP) | VAF 30/58 reads (52%) | catalogued as COSV99657944; called by muse, mutect2, varscan2
